Somatic mutation profile of tumor specimen C3N-03202-01 (aliquot CPT0185020007) from CPTAC case C3N-03202, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 68.3 years (24,932 days).
Specimen C3N-03202-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 827cf111-fce5-42d6-8ff7-b43424285053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03202-31 (Blood Derived Normal), aliquot CPT0185080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdf1b675-6696-493c-8e76-5751634a4a7d

The open-access MAF lists 44 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Intron 3, RNA 3, 5'Flank 1, Nonsense Mutation 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-6_927del p.X307_splice | Splice Site (DEL) | VAF 28/309 reads (9%) | hotspot (GDC flag); called by mutect2, pindel
- CAND2 | c.611C>A p.A204D (on ENST00000456430 / NM_001162499.2; = p.A111D on NM_012298.3) | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as COSV55990939; called by muse, mutect2
- DNAH11 | c.7249A>C p.T2417P | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100176466; called by muse, mutect2
- EWSR1 | c.1967A>T p.Y656F | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV58421658; called by muse, mutect2
- FAM117B | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57421056; called by muse, mutect2
- KCNT2 | c.314G>T p.W105L | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99652453; called by muse, mutect2
- KL | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198966; called by muse, mutect2
- OR5L1 | c.453T>A p.C151* | Nonsense Mutation (SNP) | VAF 30/290 reads (10%) | catalogued as COSV61733347; called by muse, mutect2, varscan2
- RILPL2 | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 50/595 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV54911940; called by muse, mutect2
- SLC13A3 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286192; called by muse, mutect2
- SNRPN | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100577758, COSV57594911; called by muse, mutect2
- ANKRD13D | c.*253C>A | Splice Region (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- ANKRD30A | c.3040G>A p.E1014K (on ENST00000611781; = p.E958K on NM_052997.2) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.296); called by muse, mutect2
- C12orf57 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CACNA1G | c.72C>A p.D24E | Missense Mutation (SNP) | VAF 66/520 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CSGALNACT2 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); called by muse, mutect2
- GIMAP2 | c.596T>C p.M199T | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- GYS2 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LILRB1 | c.2068G>T p.A690S (on ENST00000427581; = p.A639S on NM_006669.6) | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LRP1 | c.5068G>T p.D1690Y | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDH15 | c.4755G>T p.M1585I | Missense Mutation (SNP) | VAF 40/423 reads (9%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); called by muse, mutect2
- PCDHA11 | c.436A>C p.K146Q | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); called by muse, mutect2
- PDE1B | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.22); called by muse, mutect2
- RILPL2 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- SNRPN | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- TANC1 | c.4471C>G p.L1491V | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); called by muse, mutect2
- ZNF711 | c.2165A>C p.H722P | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CEP350 | c.1896C>T p.L632= | Silent (SNP) | VAF 25/311 reads (8%) | called by muse, mutect2
- GEMIN2 | c.9A>T p.R3= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- IFT122 | c.1056C>T p.F352= (on ENST00000348417 / NM_052989.3; = p.F293= on NM_018262.4) | Silent (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- MRE11 | c.420C>T p.A140= | Silent (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- OR10K1 | c.717C>A p.S239= | Silent (SNP) | VAF 15/552 reads (3%) | called by muse, mutect2
- PAFAH2 | c.69G>T p.V23= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- PNPLA5 | c.213C>T p.L71= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- RGS22 | c.3699G>A p.K1233= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1992A>T p.L664= | Silent (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- TRPS1 | c.1038A>G p.S346= (on ENST00000220888 / NM_001330599.2; = p.S359= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/319 reads (9%) | called by muse, mutect2
- CNKSR1 | c.1404-33C>T | Intron (SNP) | VAF 46/568 reads (8%) | called by muse, mutect2
- FAM90A27P | n.1289G>T | RNA (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2, varscan2
- RNF145 | c.-40+1292A>C | Intron (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- RNF217-AS1 | n.1198T>G | RNA (SNP) | VAF 7/171 reads (4%) | called by muse, mutect2
- SGCA | c.983+1181del | Intron (DEL) | VAF 52/367 reads (14%) | called by mutect2, pindel, varscan2
- TXNRD3 | n.658G>T | RNA (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- ZKSCAN8 | chr6:28136964 G>A | 5'Flank (SNP) | VAF 23/390 reads (6%) | called by muse, mutect2
